Somatic mutation profile of tumor specimen RC-B65L-TTP1-A (aliquot RC-B65L-TTP1-A-1-1-D-A93N-47) from RC case RC-B65L, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Alive; Primary diagnosis: Angioimmunoblastic T-cell lymphoma; Tissue or organ of origin: Lymph node, NOS; Age at diagnosis: 64.0 years (23,375 days).
Specimen RC-B65L-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d24601b8-0cdf-4062-9af3-14c3c6e00d90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B65L-NB1-A (Granulocytes; tissue type Normal), aliquot RC-B65L-NB1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c2a5757-e4c5-47c6-a1db-7d819693538d

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 2, Silent 2, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RHOA | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 12/104 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV69041529, COSV69041693, COSV69041915, COSV69043569; called by muse, mutect2, varscan2
- TET2 | c.1648C>T p.R550* | Nonsense Mutation (SNP) | VAF 33/126 reads (26%) | hotspot (GDC flag); catalogued as rs572712965, COSV54395664; called by muse, mutect2, varscan2
- ERC2 | c.1111G>C p.A371P | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2
- LAMA1 | c.7279A>C p.N2427H | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHA13 | c.1703C>G p.P568R | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.197); called by muse, mutect2
- RNF14 | c.727T>C p.C243R | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OSBPL7 | c.2202C>T p.F734= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as rs767753240; called by muse, mutect2
- POU6F1 | c.1305C>T p.V435= | Silent (SNP) | VAF 13/149 reads (9%) | catalogued as COSV61327748; called by muse, mutect2
- EYS | c.1767-7839C>T | Intron (SNP) | VAF 14/177 reads (8%) | called by muse, mutect2
- KLF17 | c.-73A>C | 5'UTR (SNP) | VAF 20/100 reads (20%) | called by muse, mutect2
- TSNARE1 | c.1363+4457C>T | Intron (SNP) | VAF 16/164 reads (10%) | called by muse, mutect2
